FM case AD12003 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/80dda09c-778e-4729-a19d-8142447d44d8

Female, 59.8 years: Renal cell carcinoma, NOS (ICD-O-3 8312/3) of the kidney; metastasis biopsied or resected from the brain. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
